CCDI case PBBTCV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9429c5b4-2c43-42b3-8468-2e7073e55227

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 8.9 years (3,266 days).

Biospecimens (3 samples)
- Sample 0DG84J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG852: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG87V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
